TARGET case TARGET-20-PAYHGK-Sorted-leukemic — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f109bf25-dee2-4dae-b44a-4534c5a16607

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.5 years (5,651 days); Year of diagnosis: 2017; Days to last follow up: 2 days.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.

Follow-up (1 entry)
- Days to follow up: 2 days; Event-free: no event (relapse, second malignancy or death) recorded through day 2; Year of follow up: 2017.

Molecular and laboratory tests
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- NPM1 mutation, nos: Positive.

Biospecimens (1 sample)
- Sample TARGET-20-PAYHGK-Sorted-leukemic-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
